Somatic mutation profile of tumor specimen MMRF_2472_1_BM_CD138pos (aliquot MMRF_2472_1_BM_CD138pos_T1_KHS5U_L11255) from MMRF case MMRF_2472, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,987 days).
Specimen MMRF_2472_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab1d8f1c-9947-4d47-a61f-a88171458b39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2472_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2472_1_PB_Whole_C2_KHS5U_L11254; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2042fb96-c6e4-4315-b9bc-25b4b1ae2ee6

The open-access MAF lists 70 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 17, Silent 11, Intron 10, Nonsense Mutation 2, 5'UTR 2, 3'Flank 2, 5'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BVES | c.920A>G p.H307R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs755973295; called by muse, mutect2, varscan2
- FMO5 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs587653353; called by muse, varscan2
- FZD2 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1414226071, COSV100190939; called by muse, mutect2, varscan2
- IGHV2-70 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs369555797; called by muse, varscan2
- IGLV3-1 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs370589387; called by muse, mutect2, varscan2
- NTRK3 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371959662, COSV62300789, COSV62310747; called by muse, mutect2, varscan2
- RELN | c.9211G>T p.E3071* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV59014413; called by muse, mutect2
- SCN7A | c.3724G>T p.G1242* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs867468672, COSV104434477; called by muse, mutect2, varscan2
- SLC7A13 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139761067; called by muse, mutect2, varscan2
- TRAPPC3 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148705774; called by muse, mutect2, varscan2
- ZNF462 | c.5060G>A p.R1687Q | Missense Mutation (SNP) | VAF 156/347 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs368842185; called by muse, mutect2, varscan2
- ZNF630 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52095638, COSV52095662; called by muse, mutect2, varscan2
- C5orf22 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- CUBN | c.10583C>T p.P3528L | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERAL1 | c.1177A>G p.K393E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HPS4 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IGHV2-70D | c.147C>G p.S49R | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, varscan2
- IRS4 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KIAA1210 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MASP1 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MYBPC2 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOP56 | c.758-3T>A | Splice Region (SNP) | VAF 75/188 reads (40%) | called by muse, mutect2, varscan2
- PRRX2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SEMA6A | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SYT1 | c.650A>C p.Y217S | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMF1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AHDC1 | c.3420C>T p.N1140= | Silent (SNP) | VAF 111/231 reads (48%) | catalogued as rs1391727575; called by muse, mutect2, varscan2
- ASPRV1 | c.747T>C p.A249= | Silent (SNP) | VAF 90/199 reads (45%) | catalogued as rs1001647646; called by muse, mutect2, varscan2
- CSTL1 | c.381C>T p.F127= | Silent (SNP) | VAF 118/278 reads (42%) | catalogued as rs267605857, COSV55677898; called by muse, mutect2, varscan2
- IGHV2-70 | c.129C>T p.F43= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as rs548066677; called by muse, varscan2
- IGHV2-70D | c.303T>G p.L101= | Silent (SNP) | VAF 34/96 reads (35%) | called by muse, varscan2
- KLHL8 | c.939G>A p.R313= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV99911252; called by muse, mutect2
- KRT7 | c.1377C>T p.T459= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs769849596, COSV57767302; called by muse, mutect2, varscan2
- MYOM2 | c.1626C>T p.L542= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs752177653; called by muse, mutect2, varscan2
- PCDHA6 | c.1302G>A p.S434= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV65341602, COSV65342476, COSV65345054; called by muse, mutect2, varscan2
- SIDT1 | c.2475T>C p.P825= | Silent (SNP) | VAF 88/228 reads (39%) | catalogued as rs1288145550; called by muse, mutect2, varscan2
- TCOF1 | c.426T>C p.P142= | Silent (SNP) | VAF 87/192 reads (45%) | called by muse, mutect2, varscan2
- AASDH | c.2488+288T>A | Intron (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- BTG2 | c.*1647T>A | 3'UTR (SNP) | VAF 64/142 reads (45%) | called by muse, mutect2, varscan2
- DBNL | c.*6924A>G | 3'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- DDO | c.*976G>T | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2
- DYM | c.1860+73C>T | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53980482; called by muse, mutect2
- EPHA7 | c.832+556A>C | Intron (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- EYS | c.1766+5256A>C | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2
- FAR1 | c.1128-1406A>G | Intron (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- FBXO21 | chr12:117145055 ins C | 3'Flank (INS) | VAF 14/45 reads (31%) | catalogued as rs142024020, COSV57971589; called by mutect2, pindel, varscan2
- FMN2 | c.*537A>G | 3'UTR (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- HDAC8 | c.738-10823G>A | Intron (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- KNDC1 | c.*704G>T | 3'UTR (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- LRP6 | c.*13C>T | 3'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- MDGA1 | c.*5226G>A | 3'UTR (SNP) | VAF 91/245 reads (37%) | catalogued as rs1056535977; called by muse, mutect2, varscan2
- MRPL36P1 | n.189G>T | RNA (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- PAX7 | c.*75G>A | 3'UTR (SNP) | VAF 43/93 reads (46%) | catalogued as rs977760922, COSV101354062; called by muse, mutect2, varscan2
- PCDH17 | c.*3959T>G | 3'UTR (SNP) | VAF 26/33 reads (79%) | called by muse, mutect2, varscan2
- PDCD5 | c.330+148G>T | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- PHPT1 | c.285+12C>T | Intron (SNP) | VAF 12/202 reads (6%) | catalogued as rs1350293152; called by muse, mutect2
- PRPF4 | c.-12C>A | 5'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- PTPRQ | c.*843A>G | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- RASSF2 | c.*3049C>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs1181003979; called by muse, mutect2, varscan2
- RPL36A | c.3+180G>C | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2
- SENP1 | c.*1085G>A | 3'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- SLITRK4 | chrX:143627040 T>G | 3'Flank (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- STAM | c.*610T>G | 3'UTR (SNP) | VAF 22/42 reads (52%) | catalogued as rs72782577; called by mutect2, varscan2
- SUSD2 | c.*133C>T | 3'UTR (SNP) | VAF 74/184 reads (40%) | called by muse, mutect2, varscan2
- TBC1D15 | c.*548T>G | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2
- TBC1D15 | c.*550T>C | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2
- TGM3 | c.-51T>A | 5'UTR (SNP) | VAF 96/213 reads (45%) | called by muse, mutect2, varscan2
- UQCC3 | c.*279T>G | 3'UTR (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864416 T>C | 5'Flank (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.588+4951A>C | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
